CCDI case PBCNCY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Renal pelvis.
https://portal.gdc.cancer.gov/cases/a8f7307c-41ae-4107-ae2f-a368432ee54c

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Tissue or organ of origin: Renal pelvis; Age at diagnosis: 2.6 years (935 days).

Biospecimens (2 samples)
- Sample 0DVR5X: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DVR8F: Tissue type: Tumor; Specimen type: Solid Tissue.
